Gene-level copy-number profile of tumor specimen TCGA-EB-A82B-01A from TCGA case TCGA-EB-A82B, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.2 years (21,249 days).
Specimen TCGA-EB-A82B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.6b95e44f-4ae9-438f-947e-9f5be03d50a7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A82B-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ae70f834-b5c2-4210-8370-ee2bf0646eac

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,259; copy number 2: 10,666; copy number 3: 17,546; copy number 4: 21,871; copy number 5: 6,209; copy number 6: 863; copy number 7: 434; copy number 8: 235; copy number 9: 246; copy number 10: 69; copy number 11: 2; copy number 12: 3; copy number 13: 76; copy number 14: 80; copy number 18: 68; copy number 19: 28; copy number 21: 10; copy number 24: 14; copy number 25: 41; copy number 29: 20; copy number 32: 15; copy number 36: 57.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A82B-01A-11D-A34T-01): tumor purity 0.46, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 729 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:27,649,419–28,193,936, 31 genes, copy number 10: AL031729.1, LINC02574, IFI6, AL445490.1, RNU6-949P, CHMP1AP1, RNU6-424P, AL020997.5, FAM76A, AL020997.1, RPEP3, STX12, AL020997.2, AL020997.3, RNU6-1245P, AL020997.4, PPP1R8, SCARNA1, THEMIS2, RPA2, SMPDL3B, AL512288.1, XKR8, EYA3, AL512288.2, RN7SL559P, SPCS2P4, AL137792.2, AL137792.1, RNU6-176P, PTAFR.
- chr4:19,172,335–19,456,994, 1 gene, copy number 11 (within-gene range 7–11): LINC02438.
- chr4:19,257,951–19,258,337, 1 gene, copy number 11: AC024595.1.
- chr6:54,770,583–65,707,226, 82 genes, copy number 10–36 (within-gene range 2–36) (broad region; genes not listed).
- chr6:167,146,414–168,101,511, 25 genes, copy number 13–24: TCP10L2, GPR31, AL121935.3, AL353747.1, HPAT5, AL353747.3, AL353747.2, UNC93A, TTLL2, AL021331.1, TCP10L3, AL356123.1, LINC02538, AL356123.2, LINC02487, AL009178.1, LINC01558, AL009178.2, AL009178.3, AFDN-DT, AFDN, HGC6.3, KIF25-AS1, KIF25, FRMD1.
- chr11:66,312,853–74,669,117, 329 genes, copy number 9–18 (broad region; genes not listed).
- chr11:76,759,916–78,582,156, 51 genes, copy number 13–36: AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr11:78,749,250–78,756,480, 1 gene, copy number 36: AP002768.1.
- chr11:100,687,288–102,628,070, 30 genes, copy number 25–32 (within-gene range 5–32): ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1.
- chr12:66,347,431–67,069,162, 1 gene, copy number 9 (within-gene range 4–9): GRIP1.
- chr12:66,950,754–74,402,600, 122 genes, copy number 9–19 (within-gene range 3–21) (broad region; genes not listed).
- chr13:31,311,289–31,483,699, 3 genes, copy number 12: ANKRD26P4, AL161616.2, AL161616.1.
- chr13:31,846,713–32,299,125, 1 gene, copy number 9 (within-gene range 7–9): FRY.
- chr13:32,025,314–36,131,382, 47 genes, copy number 9: FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1, LINC00423, TOMM22P3, KL, STARD13, STARD13-IT1, STARD13-AS, AL627232.1, LINC02344, AL138999.2, AL138999.1, AL139383.1, AL161719.1, AL139081.1, AL139081.2, RFC3, RNU5A-4P, AL161891.1, AL160394.2, VDAC1P12, AL160394.1, AL356321.1, LINC02343, LINC00457, AL161716.1, GAMTP2, Metazoa_SRP, AL138690.1, NBEA, SCAND3P1, PHBP13, MAB21L1, AL390071.1, LINC00445, DCLK1.
- chr20:26,135,983–26,251,546, 4 genes, copy number 9 (within-gene range 8–9): AL121904.2, MIR663AHG, AL121904.1, MIR663A.

Autosomal genes at a single copy (total copy number 1): 1,259. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
